Somatic mutation profile of tumor specimen TCGA-17-Z045-01A (aliquot TCGA-17-Z045-01A-01W-0746-08) from TCGA case TCGA-17-Z045, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z045-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f73645ec-c107-452c-877d-410d70abb203.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z045-11A (Solid Tissue Normal), aliquot TCGA-17-Z045-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aabe0340-0c7d-46ca-9a14-70b80e767002

The open-access MAF lists 738 somatic variants for this specimen: 555 protein-altering or splice-affecting, 163 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 467, Silent 163, Nonsense Mutation 38, Splice Site 24, Frame Shift Del 13, Intron 9, Frame Shift Ins 9, RNA 4, Splice Region 3, 3'UTR 3, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1775G>T p.R592I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs774780856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR2 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs1160915890; called by muse, mutect2, varscan2
- ADAM20 | c.748G>T p.V250F | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1371335369; called by muse, mutect2, varscan2
- ADGRL2 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV54655136, COSV54656571; called by muse, mutect2, varscan2
- AFF1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 111/478 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313398889; called by muse, mutect2, varscan2
- AGBL1 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.649); catalogued as rs1326463703; called by muse, mutect2, varscan2
- AGT | c.530C>A p.A177E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV64183680; called by mutect2, varscan2
- AHCTF1 | c.1223-1G>T p.X408_splice (on ENST00000366508; = p.X382_splice on NM_015446.5) | Splice Site (SNP) | VAF 14/45 reads (31%) | catalogued as rs1463891031; called by muse, mutect2, varscan2
- AKAP9 | c.8636G>T p.R2879M (on ENST00000359028; = p.R2855M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100661744; called by muse, mutect2, varscan2
- AMBN | c.801C>A p.G267= | Splice Region (SNP) | VAF 14/46 reads (30%) | catalogued as rs763983609; called by muse, mutect2, varscan2
- AMER1 | c.3266G>T p.R1089M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV57668038, COSV57671296; called by muse, mutect2, varscan2
- AMOT | c.3131G>C p.S1044T (on ENST00000371959 / NM_001113490.1; = p.S635T on NM_133265.3) | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs781294453; called by muse, mutect2
- ASTN2 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100530154; called by muse, mutect2, varscan2
- ATAD2 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); catalogued as COSV54876942, COSV54880175; called by muse, mutect2, varscan2
- AXL | c.1268T>A p.L423Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56565377; called by muse, mutect2, varscan2
- B2M | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 9/126 reads (7%) | catalogued as COSV62563509; called by muse, mutect2
- BCHE | c.1403A>G p.Y468C | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52254258; called by muse, mutect2, varscan2
- BPI | c.1255C>A p.L419M (on ENST00000262865; = p.L415M on NM_001725.3) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1467896479; called by muse, mutect2, varscan2
- C1GALT1C1 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV58973879; called by muse, mutect2, varscan2
- C1orf74 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs1428281209; called by muse, mutect2, varscan2
- CACNA1E | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62427628; called by muse, mutect2, varscan2
- CASP10 | c.965A>G p.H322R (on ENST00000272879 / NM_032974.5; = p.H279R on NM_001230.5) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1303094933; called by muse, mutect2, varscan2
- CCDC158 | c.3002G>C p.S1001T | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs1051659755; called by muse, mutect2, varscan2
- CCDC33 | c.1755G>T p.Q585H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.66); catalogued as rs1183495538; called by muse, mutect2, varscan2
- CDAN1 | c.3022G>T p.G1008W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs948707524; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs779604029; called by muse, mutect2, varscan2
- CFAP57 | c.728C>A p.S243* | Nonsense Mutation (SNP) | VAF 44/241 reads (18%) | catalogued as COSV100993836; called by muse, mutect2, varscan2
- CLCN1 | c.411C>A p.Y137* | Nonsense Mutation (SNP) | VAF 81/291 reads (28%) | catalogued as rs773806167, CM082567; called by muse, mutect2, varscan2
- CMKLR1 | c.339G>T p.K113N (on ENST00000312143 / NM_001142344.2; = p.K111N on NM_004072.3) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56441394; called by muse, mutect2, varscan2
- CNGB3 | c.710C>A p.P237Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760338963; called by muse, mutect2
- CNTN1 | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1171540255, COSV61641766; called by muse, mutect2, varscan2
- COL5A3 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1178625436; called by muse, mutect2, varscan2
- COL9A1 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57878757; called by muse, varscan2
- CRACD | c.2665G>C p.A889P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1315300283, COSV51714224, COSV51735460; called by muse, mutect2, varscan2
- CREB3L4 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs763524911; called by muse, mutect2, varscan2
- CSMD2 | c.2716G>T p.E906* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV53970743; called by muse, mutect2, varscan2
- CSMD3 | c.10868C>A p.P3623H (on ENST00000297405 / NM_001363185.1; = p.P3454H on NM_052900.3) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.366); catalogued as rs1470468550, COSV52296496; called by muse, mutect2, varscan2
- CSRNP3 | c.1400T>C p.L467P | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.808); catalogued as rs1288379812; called by muse, mutect2, varscan2
- CYP4V2 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV66504833; called by muse, mutect2, varscan2
- DCAF4L2 | c.528G>C p.M176I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV60479414; called by muse, mutect2, varscan2
- DEFB126 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1299590006, COSV101215663; called by muse, mutect2, varscan2
- DENND2C | c.1815+2T>A p.X605_splice (on ENST00000393274 / NM_001256404.2; = p.X548_splice on NM_198459.4) | Splice Site (SNP) | VAF 138/394 reads (35%) | catalogued as rs1238716014; called by muse, mutect2, varscan2
- DHX36 | c.704del p.G235Afs*25 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as COSV100273449; called by mutect2, pindel, varscan2
- DMD | c.7130C>A p.P2377Q | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV58941566; called by muse, mutect2, varscan2
- DMD | c.5101C>A p.L1701I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV63793994; called by muse, mutect2, varscan2
- DNAH7 | c.2483G>T p.R828I | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as rs758204551, COSV56754360; called by muse, mutect2, varscan2
- DNAH9 | c.6877G>T p.G2293* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV52382447; called by muse, mutect2, varscan2
- DNAJC5B | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV52538563; called by muse, mutect2, varscan2
- DNMBP | c.3157G>T p.E1053* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs1286700690; called by muse, mutect2, varscan2
- DOCK2 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.855); catalogued as rs1487972151; called by muse, mutect2, varscan2
- DOCK4 | c.3442G>T p.G1148C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1417963577; called by muse, mutect2, varscan2
- ECEL1 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV58814152; called by muse, mutect2, varscan2
- ECT2L | c.1654C>G p.L552V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs1234504191; called by muse, mutect2
- EDIL3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99675324; called by muse, mutect2, varscan2
- EPB41L1 | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs750417342, COSV52433127, COSV52443756; called by muse, mutect2, varscan2
- EPHA5 | c.2939G>T p.G980V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99896405; called by muse, mutect2, varscan2
- EPO | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53162074; called by muse, mutect2
- ERICH3 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as rs765975754, COSV100443927; called by muse, mutect2, varscan2
- EYS | c.939T>G p.S313R | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.076); catalogued as rs774342993, COSV60988878; called by muse, mutect2, varscan2
- FERMT2 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751620780, COSV58406431; called by mutect2, varscan2
- FLNC | c.2258C>G p.P753R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368639; called by muse, mutect2, varscan2
- GABRA6 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV50890489; called by muse, mutect2, varscan2
- GGN | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.289); catalogued as COSV53056511; called by muse, mutect2, varscan2
- GIMAP1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759086093, COSV56187156; called by muse, mutect2
- GKN2 | c.420G>C p.E140D | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100187910; called by muse, mutect2, varscan2
- GLI2 | c.3194C>A p.T1065N (on ENST00000361492 / NM_001374353.1; = p.T1082N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as COSV58044120; called by muse, mutect2, varscan2
- GOLGB1 | c.5191G>T p.V1731F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs1173753324; called by muse, mutect2, varscan2
- GPR101 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); catalogued as COSV53237794; called by muse, mutect2, varscan2
- GPR101 | c.258del p.W87Gfs*57 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs1339496374; called by mutect2, pindel, varscan2
- GPRC5B | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435138421; called by muse, mutect2, varscan2
- GRID2 | c.1998-1G>T p.X666_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as rs1438971330; called by muse, mutect2, varscan2
- H2BC9 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1234401469, COSV55100851; called by muse, mutect2
- HCRTR1 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV65486284; called by muse, mutect2, varscan2
- HIPK2 | c.3236G>T p.S1079I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs1363466282; called by muse, mutect2, varscan2
- HMCN1 | c.7707A>G p.V2569= | Splice Region (SNP) | VAF 19/59 reads (32%) | catalogued as rs1236753088; called by muse, mutect2, varscan2
- HTR7 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.834); catalogued as COSV53285138; called by muse, mutect2, varscan2
- IGDCC4 | c.3490C>A p.P1164T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as rs1234225006; called by muse, mutect2
- IGSF11 | c.972C>A p.N324K (on ENST00000393775 / NM_001015887.3; = p.N323K on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs1171838551, COSV61170567; called by muse, mutect2, varscan2
- IL18RAP | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as rs369615964; called by muse, mutect2, varscan2
- ITM2A | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV64810972; called by muse, mutect2, varscan2
- JAML | c.1096C>A p.P366T (on ENST00000356289 / NM_001098526.2; = p.P356T on NM_153206.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52627751; called by muse, mutect2, varscan2
- KCNA10 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs529447404; called by muse, mutect2, varscan2
- KCNH8 | c.970-1G>T p.X324_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | catalogued as rs1248465063, COSV100110315; called by muse, mutect2, varscan2
- KCNN2 | c.1687A>T p.R563W (on ENST00000264773; = p.R775W on NM_021614.4) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as rs761122529; called by muse, mutect2, varscan2
- KIAA0586 | c.986G>A p.R329H (on ENST00000619416 / NM_001244190.2; = p.R344H on NM_014749.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773375756, COSV99039108, COSV99707856; called by muse, mutect2, varscan2
- KLHL12 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1394386240; called by muse, mutect2, varscan2
- KRT40 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100898884; called by muse, mutect2, varscan2
- KRTAP10-4 | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59961676; called by muse, mutect2, varscan2
- L1CAM | c.2120T>C p.V707A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.132); catalogued as CM138911; called by muse, mutect2, varscan2
- LHCGR | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV54302817; called by muse, mutect2, varscan2
- LIPI | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs372388132, COSV60715565; called by muse, mutect2, varscan2
- LONRF2 | c.2038G>C p.G680R | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66542621; called by muse, mutect2, varscan2
- LRP1B | c.12020C>A p.S4007Y | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV67273514; called by muse, mutect2, varscan2
- LRP1B | c.8673C>A p.C2891* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs1379443414, COSV67276588; called by muse, varscan2
- LRP1B | c.2017G>T p.V673L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.355); catalogued as COSV67197634, COSV67202427; called by muse, mutect2, varscan2
- LTBP1 | c.2139C>G p.H713Q (on ENST00000404816 / NM_206943.4; = p.H387Q on NM_000627.4) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs962977372; called by muse, mutect2, varscan2
- LURAP1 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64338046; called by muse, varscan2
- MAGEA10 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as COSV54883044; called by muse, mutect2, varscan2
- MAGEA10 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.411); catalogued as COSV54882942; called by muse, mutect2, varscan2
- MAGEC2 | c.290A>T p.Q97L | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as rs1393825660; called by muse, mutect2, varscan2
- METAP1D | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59928748; called by muse, mutect2, varscan2
- MPP4 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.71); catalogued as rs765946151; called by muse, mutect2, varscan2
- MS4A14 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs1397434164; called by muse, mutect2, varscan2
- MUC16 | c.21617C>T p.S7206F | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV67444771; called by muse, mutect2, varscan2
- MUC20 | c.1581G>T p.R527S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs750854832, COSV57846796; called by muse, mutect2, varscan2
- MYCL | c.908C>G p.A303G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65693368; called by muse, mutect2, varscan2
- MYO18B | c.2049T>A p.S683R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59140810; called by muse, mutect2, varscan2
- MYO3B | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58697849; called by muse, mutect2, varscan2
- NARF | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1246347200; called by muse, mutect2, varscan2
- NAV3 | c.1908G>T p.R636S | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs1477029866, COSV57070336, COSV57107421; called by muse, mutect2, varscan2
- NCAM2 | c.1624T>G p.W542G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs769962500; called by muse, mutect2, varscan2
- NCAN | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV53057561; called by muse, mutect2, varscan2
- NCR1 | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759022000, COSV52555719; called by muse, mutect2, varscan2
- NDST4 | c.1848G>T p.M616I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs1380671232; called by muse, mutect2, varscan2
- NEB | c.11085C>A p.Y3695* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs1446812018; called by muse, mutect2, varscan2
- NFKBIA | c.688C>G p.P230A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs894738851; called by muse, mutect2, varscan2
- NLRP3 | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.118); catalogued as rs1219334346, COSV60221224, COSV60224831; called by muse, mutect2, varscan2
- NPAP1 | c.1988G>T p.S663I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV61512021; called by muse, mutect2, varscan2
- NPAP1 | c.2426G>T p.S809I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as rs1279103259; called by muse, mutect2, varscan2
- NRIP1 | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV59655256; called by muse, mutect2, varscan2
- NUCKS1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV63347915; called by muse, mutect2, varscan2
- NYNRIN | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs1354469924; called by muse, mutect2, varscan2
- OOSP2 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1194533346; called by muse, mutect2, varscan2
- OPHN1 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 52/96 reads (54%) | catalogued as rs1282812430; called by muse, mutect2, varscan2
- OR2A12 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs760660873; called by muse, mutect2, varscan2
- OR2A25 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV68716851; called by muse, mutect2, varscan2
- OR2T11 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100424791; called by muse, mutect2, varscan2
- OR2T12 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as rs777107229; called by muse, mutect2, varscan2
- OR4N2 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs748796945; called by muse, mutect2, varscan2
- OR51G2 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs760144153, COSV100432256, COSV58992710; called by muse, mutect2, varscan2
- OR51V1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1448257518; called by muse, mutect2, varscan2
- OR5D16 | c.320G>C p.C107S | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV65722043; called by muse, mutect2, varscan2
- OR5R1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1442805972; called by muse, mutect2, varscan2
- OR8J3 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100041017; called by muse, mutect2, varscan2
- OSBPL8 | c.2306A>G p.K769R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs543516874; called by muse, mutect2, varscan2
- PCDHA2 | c.1699G>T p.A567S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1420161301; called by muse, mutect2, varscan2
- PCDHA8 | c.297C>G p.S99R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.137); catalogued as rs782778902; called by muse, mutect2, varscan2
- PCDHB12 | c.1629C>A p.S543R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV53396471; called by muse, mutect2, varscan2
- PCDHB15 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV50861572; called by muse, mutect2, varscan2
- PCDHB9 | c.2161T>A p.S721T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.167); catalogued as COSV53377066; called by muse, mutect2, varscan2
- PCDHGA8 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); catalogued as COSV53938644; called by muse, mutect2, varscan2
- PIK3R5 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as rs774252675; called by muse, mutect2, varscan2
- PKHD1 | c.6543G>T p.R2181S | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1317660982; called by muse, mutect2, varscan2
- PLB1 | c.2845C>G p.R949G | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as CM141399; called by muse, mutect2, varscan2
- PLSCR4 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs745956616, COSV61607916; called by muse, mutect2, varscan2
- PPM1B | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56766989; called by muse, mutect2, varscan2
- PRDX1 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1380700781; called by muse, mutect2, varscan2
- PRKCG | c.327C>A p.S109R | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as COSV54725510; called by muse, mutect2, varscan2
- PRKD1 | c.2227G>T p.V743L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs1225664385, COSV59561798; called by muse, mutect2, varscan2
- PRMT6 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1435002258; called by muse, mutect2, varscan2
- PTPN3 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); catalogued as rs769409923, COSV52710375; called by muse, mutect2, varscan2
- PXDN | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1343134077; called by muse, mutect2, varscan2
- RAB3C | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 27/119 reads (23%) | catalogued as rs140644565; called by muse, mutect2, varscan2
- RALGPS1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1230257496; called by muse, mutect2, varscan2
- RBM43 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58878467; called by muse, mutect2, varscan2
- REG3G | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV55448569, COSV55449491; called by muse, mutect2, varscan2
- RHOJ | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753578867, COSV57460880; called by muse, mutect2, varscan2
- RIMS3 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); catalogued as rs1432477522; called by mutect2, varscan2
- RPE65 | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV99254201; called by muse, mutect2
- RPL10 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV99185885; called by muse, mutect2, varscan2
- RTL9 | c.3043G>A p.A1015T | Missense Mutation (SNP) | VAF 41/692 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs754557668; called by muse, mutect2
- RXFP1 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs866857541, COSV57046717; called by muse, mutect2
- RYR1 | c.4996C>A p.L1666M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289031714; called by muse, mutect2, varscan2
- RYR2 | c.1016A>T p.D339V | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100772501; called by muse, mutect2, varscan2
- SEMA5A | c.271-2A>T p.X91_splice | Splice Site (SNP) | VAF 27/94 reads (29%) | catalogued as COSV101228559; called by muse, mutect2, varscan2
- SEPTIN12 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766733114, COSV51616816; called by muse, mutect2, varscan2
- SETBP1 | c.2911del p.H971Tfs*43 | Frame Shift Del (DEL) | VAF 37/135 reads (27%) | catalogued as COSV99952690; called by mutect2, pindel, varscan2
- SHCBP1L | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777059000, COSV62356732; called by muse, mutect2, varscan2
- SIPA1L1 | c.4199G>T p.S1400I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV62171452; called by muse, mutect2, varscan2
- SLC14A1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100425148; called by muse, mutect2, varscan2
- SLC15A2 | c.685del p.V229* | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | catalogued as COSV99815604; called by mutect2, pindel, varscan2
- SLC17A2 | c.553G>C p.A185P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99614180; called by muse, mutect2, varscan2
- SLC1A3 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs1445927150; called by muse, mutect2, varscan2
- SLC23A2 | c.1762G>T p.V588L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as COSV57774317; called by muse, mutect2, varscan2
- SLC6A15 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99880367; called by muse, mutect2, varscan2
- SLCO1C1 | c.884T>A p.L295* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV56870157; called by muse, mutect2, varscan2
- SNTG1 | c.1126A>G p.S376G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV52475229; called by muse, mutect2
- SOBP | c.2305G>C p.E769Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58001497; called by muse, mutect2
- SPANXB1 | c.39C>A p.S13R | Missense Mutation (SNP) | VAF 52/1023 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); catalogued as rs1161024464; called by muse, mutect2
- SRD5A3 | c.713G>C p.C238S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs761579478; called by muse, mutect2, varscan2
- ST18 | c.3056T>C p.M1019T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1307824064; called by muse, mutect2, varscan2
- STIM2 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs144093498; called by muse, mutect2, varscan2
- SUN3 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV52051399; called by muse, mutect2, varscan2
- SV2C | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs758651691, COSV59213838; called by muse, mutect2, varscan2
- TAAR6 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV99256404; called by muse, mutect2, varscan2
- TENM2 | c.7883A>T p.D2628V (on ENST00000518659 / NM_001122679.2; = p.D2389V on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs1395184497; called by muse, mutect2, varscan2
- TENM3 | c.4151G>C p.C1384S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV69313168; called by muse, mutect2, varscan2
- TEX10 | c.1981T>G p.S661A | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV66514297; called by muse, mutect2, varscan2
- TNPO3 | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs749570438; called by muse, mutect2, varscan2
- TOM1L1 | c.223-2A>T p.X75_splice | Splice Site (SNP) | VAF 17/51 reads (33%) | catalogued as rs1378519814; called by muse, mutect2, varscan2
- TPO | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs144957846; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRABD2A | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196866588; called by muse, mutect2, varscan2
- TRAJ58 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs1192841064; called by muse, mutect2, varscan2
- TRIM9 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV53614703, COSV53624455; called by muse, mutect2, varscan2
- TRPC5 | c.1582C>A p.L528I | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53288004; called by muse, mutect2, varscan2
- TSHR | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV53316187, COSV53321623; called by muse, mutect2, varscan2
- TTK | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs368624175; called by muse, mutect2, varscan2
- TTLL2 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV53443003; called by muse, mutect2, varscan2
- TTN | c.17957C>G p.T5986S (on ENST00000591111; = p.T5059S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | PolyPhen benign (0.006); catalogued as rs1453323223; called by muse, mutect2, varscan2
- TXLNB | c.1443C>A p.N481K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV64445537; called by muse, mutect2, varscan2
- TYRO3 | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV99777613; called by muse, mutect2
- USH2A | c.4784C>T p.T1595I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.425); catalogued as rs1037289217; called by muse, mutect2, varscan2
- USP28 | c.2390G>T p.G797V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs763383131; called by muse, mutect2, varscan2
- VAV3 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.317); catalogued as COSV100580358; called by muse, mutect2, varscan2
- VCAN | c.3149G>T p.S1050I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1298901348; called by muse, mutect2, varscan2
- VCP | c.2231G>T p.R744L | Missense Mutation (SNP) | VAF 151/461 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734184; called by muse, mutect2, varscan2
- VIL1 | c.550C>A p.R184S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.042); catalogued as COSV50289004; called by muse, mutect2, varscan2
- WDR47 | c.2292G>T p.W764C (on ENST00000369962 / NM_001142551.2; = p.W765C on NM_014969.5) | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63060393; called by muse, mutect2, varscan2
- WNT7A | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1338142209, COSV53199258; called by muse, mutect2, varscan2
- ZBBX | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1253075716; called by muse, mutect2
- ZC2HC1A | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1366664604; called by muse, mutect2, varscan2
- ZFHX4 | c.3644A>T p.Q1215L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1414086513; called by muse, mutect2, varscan2
- ZNF23 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61841609; called by muse, mutect2, varscan2
- ZNF496 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99666324; called by muse, mutect2, varscan2
- ZNF536 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as rs1354806722, COSV62821474, COSV62823957; called by muse, varscan2
- ZNF536 | c.2324-1G>A p.X775_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100834888; called by muse, mutect2, varscan2
- ZNF665 | c.26A>C p.K9T (on ENST00000600412; = p.K74T on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1267772087; called by muse, mutect2, varscan2
- ZP4 | c.353A>T p.K118M | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs953013958; called by muse, mutect2, varscan2
- ABCA1 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM4 | c.1201G>T p.V401F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM20 | c.56T>A p.F19Y | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ADAMTS5 | c.902T>G p.L301R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- ADAMTS6 | c.895G>C p.V299L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ADGRG4 | c.2636C>G p.T879R | Missense Mutation (SNP) | VAF 279/1131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AFF2 | c.3410C>G p.A1137G | Missense Mutation (SNP) | VAF 105/360 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AGAP3 | c.2600A>T p.E867V (on ENST00000622464; = p.E903V on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- AHCTF1 | c.1223-2A>T p.X408_splice (on ENST00000366508; = p.X382_splice on NM_015446.5) | Splice Site (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- AKNAD1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ANAPC7 | c.1235-1G>T p.X412_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- ANK2 | c.3905T>C p.I1302T | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANKS4B | c.381G>C p.M127I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP3S1 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- APC | c.6016G>C p.G2006R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- APOB | c.4072C>A p.L1358I | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AQR | c.1718A>T p.Y573F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP17 | c.1402A>T p.T468S | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ARHGAP31 | c.2800C>A p.L934I | Missense Mutation (SNP) | VAF 231/714 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ASAP2 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASTN2 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP11C | c.2536A>G p.R846G | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP1B4 | c.716G>T p.G239V (on ENST00000218008 / NM_001142447.3; = p.G235V on NM_012069.5) | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V0D1 | c.197C>A p.T66K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- BEX1 | c.87del p.N29Kfs*38 | Frame Shift Del (DEL) | VAF 81/357 reads (23%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.1688T>G p.L563R | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BOC | c.2720C>A p.P907Q | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BPGM | c.255G>T p.W85C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTLA | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- C12orf50 | c.1142C>A p.T381K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- C12orf65 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CA5B | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPN6 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 284/1246 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC158 | c.1661A>T p.K554I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CCDC39 | c.135A>C p.L45F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CCDC6 | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CD22 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CD22 | c.1507+1G>T p.X503_splice | Splice Site (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
- CD300C | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH2 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CDH20 | c.1901-1G>A p.X634_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- CDH24 | c.1087G>T p.V363L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.351); called by muse, varscan2
- CFAP52 | c.831A>C p.K277N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFHR1 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CHIA | c.953G>A p.W318* (on ENST00000343320; = p.W210* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- CHM | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- CHRM3 | c.1516C>G p.P506A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHUK | c.1680-2A>G p.X560_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- CIB2 | c.52-1G>T p.X18_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- CLIP2 | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP2 | c.3635C>A p.S1212Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CNTNAP5 | c.2886C>A p.S962R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- COL15A1 | c.3218G>T p.G1073V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL1A1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL1A2 | c.2734G>C p.V912L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- COL22A1 | c.4465C>A p.P1489T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- COL3A1 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- COPS7B | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYFIP1 | c.2200C>A p.Q734K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- CYP2A7 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DCAF12L1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- DCLRE1A | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DDX27 | c.388A>T p.T130S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLD | c.959A>T p.K320M | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- DNAH11 | c.12956C>A p.A4319D | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH3 | c.7411G>C p.E2471Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DNAH7 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2, varscan2
- DNAH7 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, varscan2
- DNAH8 | c.12720G>C p.E4240D | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- DNAJC6 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- DNM1 | c.946A>T p.N316Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- DNTTIP1 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOCK10 | c.5844G>T p.Q1948H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOP1B | c.1404C>G p.S468R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DPY19L2 | c.1884A>C p.K628N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2
- DSG3 | c.181G>T p.G61* | Nonsense Mutation (SNP) | VAF 33/167 reads (20%) | called by muse, mutect2, varscan2
- EMSY | c.3392C>T p.P1131L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMSY | c.3730G>A p.G1244S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENOX2 | c.1044G>T p.W348C (on ENST00000338144 / NM_001382520.1; = p.W319C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EP400 | c.1561_1562insG p.P521Rfs*17 | Frame Shift Ins (INS) | VAF 30/105 reads (29%) | called by mutect2, pindel, varscan2
- EPG5 | c.4044G>T p.L1348F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EPHA5 | c.1918G>T p.G640W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERICH3 | c.4057G>A p.A1353T | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ETNPPL | c.863G>T p.C288F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- EXD2 | c.1136A>G p.Y379C (on ENST00000312994 / NM_001193362.1; = p.Y254C on NM_018199.3) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F5 | c.884C>A p.T295N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM135B | c.3694dup p.R1232Pfs*31 | Frame Shift Ins (INS) | VAF 30/114 reads (26%) | called by mutect2, pindel, varscan2
- FAT1 | c.9847A>T p.K3283* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- FBLN7 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- FCRL5 | c.1019C>A p.S340Y | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FGA | c.1329G>T p.R443S | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLNC | c.4378dup p.R1460Pfs*51 | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- FMN2 | c.2068A>G p.I690V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- FSCB | c.451G>C p.V151L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FSCN1 | c.833-1G>A p.X278_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- FSTL1 | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FUT9 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FYB1 | c.53G>T p.S18I | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALNT1 | c.800G>A p.W267* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- GALNT16 | c.981G>T p.R327S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAS2L2 | c.820T>A p.C274S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GDF6 | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GKN1 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GLRX5 | c.451A>T p.K151* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- GPR20 | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GPR61 | c.783C>A p.S261R | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRID2 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- GRIK2 | c.2294G>C p.G765A | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTCD | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- HAPLN1 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HFM1 | c.3341T>C p.I1114T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HIP1 | c.1033A>T p.N345Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- HK3 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HMCN1 | c.11074T>C p.C3692R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMGCS1 | c.199T>G p.S67A | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3C | c.276T>A p.D92E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HYAL4 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IFT172 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | called by muse, varscan2
- IGF2R | c.4981G>T p.V1661F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- IGHV4-61 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- IGSF1 | c.1861G>T p.E621* | Nonsense Mutation (SNP) | VAF 51/175 reads (29%) | called by muse, mutect2, varscan2
- IGSF22 | c.1295A>T p.E432V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- IKZF1 | c.731C>G p.T244S | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPDH1 | c.1122G>C p.K374N (on ENST00000470772 / NM_001142573.2; = p.K460N on NM_000883.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- ING4 | c.421G>T p.A141S (on ENST00000396807 / NM_001127582.2; = p.A140S on NM_016162.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INHBA | c.1164dup p.S389Ifs*17 | Frame Shift Ins (INS) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- IPO8 | c.2315G>C p.G772A | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ITGA2 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KANSL1 | c.1949A>T p.Y650F | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- KCNS3 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- KIAA1549 | c.2660G>C p.S887T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- KIAA1841 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.28T>C p.C10R | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KRT15 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT5 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KRTAP26-1 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- LACRT | c.85G>C p.A29P | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- LAMA2 | c.5848del p.H1950Mfs*14 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- LAMB4 | c.2989A>T p.N997Y | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LANCL3 | c.696G>T p.L232F | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LARP1B | c.85A>G p.R29G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LCE1E | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LCT | c.4486C>G p.L1496V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- LILRA1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LMNB1 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- LRP1B | c.9785A>T p.Q3262L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRP4 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRIQ1 | c.4485G>T p.W1495C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LRRIQ3 | c.1682A>G p.Y561C | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LUM | c.473T>A p.L158* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- LYST | c.1906G>C p.A636P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- M1AP | c.902C>A p.S301* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- MAGEA10 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP2 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAP3K3 | c.1528del p.A510Pfs*25 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, varscan2
- MED8 | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 104/283 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFAP3L | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MGAT4C | c.809del p.P270Hfs*8 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, varscan2
- MLXIPL | c.1882G>C p.V628L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMD2 | c.662T>A p.L221Q (on ENST00000404774 / NM_001100600.2; = p.L197Q on NM_198403.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MME | c.1367A>G p.D456G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MMP16 | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- MMP19 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MMP8 | c.1076A>C p.Q359P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MRE11 | c.1510T>G p.F504V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- MROH2B | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH8 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MTSS1 | c.1653C>A p.N551K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by mutect2, varscan2
- MTSS2 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2
- MUC17 | c.3781A>G p.T1261A | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC17 | c.10660G>C p.A3554P | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC7 | c.322dup p.T108Nfs*39 | Frame Shift Ins (INS) | VAF 20/96 reads (21%) | called by pindel, varscan2
- MYH1 | c.2732A>T p.Q911L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- N4BP2 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- NAPB | c.562-2A>G p.X188_splice | Splice Site (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- NAV3 | c.4354C>T p.L1452F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPD3 | c.2895G>C p.M965I | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NCKAP5 | c.2450T>C p.M817T | Missense Mutation (SNP) | VAF 62/235 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCKAP5 | c.1779A>G p.I593M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- NDUFS1 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEDD1 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEO1 | c.2495-1G>T p.X832_splice | Splice Site (SNP) | VAF 38/217 reads (18%) | called by muse, mutect2, varscan2
- NKTR | c.3607A>T p.S1203C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- NPY1R | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- NT5DC3 | c.1189-1G>T p.X397_splice | Splice Site (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2
- NUP205 | c.4532A>G p.Q1511R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NWD1 | c.4417G>T p.V1473F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NXPH2 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ODF2L | c.1254+1G>T p.X418_splice (on ENST00000317336; = p.X389_splice on NM_020729.3) | Splice Site (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- OR10A5 | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- OR1L6 | c.417C>A p.Y139* (on ENST00000373684; = p.Y103* on NM_001004453.2) | Nonsense Mutation (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- OR2M3 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR2T2 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2T3 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 80/630 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.25); called by muse, mutect2
- OR4F17 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 60/583 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR52B2 | c.6T>G p.S2R | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR52L1 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5AC2 | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR5L2 | c.593T>A p.L198Q | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- OR6C74 | c.768G>C p.M256I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OSBPL1A | c.907T>A p.C303S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OTUD7A | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PABPC3 | c.505T>A p.F169I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PAN2 | c.3414G>C p.E1138D (on ENST00000425394 / NM_001127460.3; = p.E1134D on NM_014871.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.4826C>A p.T1609N | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PCDH17 | c.2423C>A p.S808* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- PCLO | c.15395A>C p.H5132P | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDE10A | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PDZRN4 | c.1240C>G p.L414V (on ENST00000402685 / NM_001164595.2; = p.L156V on NM_013377.4) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIGG | c.2713T>C p.F905L (on ENST00000453061 / NM_001127178.3; = p.F897L on NM_017733.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PIKFYVE | c.442-1G>T p.X148_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6746T>A p.I2249N | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PMS2 | c.1077G>C p.L359F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- POP1 | c.1981G>T p.G661C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- POSTN | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- POTEA | c.1271C>A p.S424* (on ENST00000519951 / NM_001005365.2; = p.S378* on NM_001002920.1) | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- PPARGC1A | c.2238dup p.E747* | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- PPP1R36 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PRAMEF15 | c.360A>C p.E120D | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by mutect2, varscan2
- PRAMEF19 | c.1411A>T p.N471Y | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, varscan2
- PRAMEF5 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PRG4 | c.250T>A p.C84S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKAR1B | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PRRC1 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTGIR | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRB | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRD | c.5127A>G p.R1709= | Splice Region (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- PTPRU | c.1567A>T p.S523C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PXDNL | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PYHIN1 | c.1196A>T p.Q399L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PZP | c.3588G>T p.K1196N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- QKI | c.585G>T p.M195I | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RAB5C | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RAD51AP2 | c.2012G>A p.S671N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- RAP1GDS1 | c.637+1del | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- RELN | c.6388C>A p.P2130T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- RFX6 | c.2398+1G>A p.X800_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- RNF103 | c.1495dup p.W499Lfs*9 | Frame Shift Ins (INS) | VAF 27/128 reads (21%) | called by mutect2, pindel, varscan2
- RNGTT | c.1539A>T p.K513N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RORC | c.1533G>T p.E511D | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RPUSD4 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTTN | c.2127G>T p.W709C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.2660A>T p.E887V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SATB1 | c.1317_1318del p.D441Pfs*41 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | called by mutect2, pindel, varscan2
- SCAPER | c.4154A>T p.Q1385L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- SEC23IP | c.2352G>C p.E784D | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SEMA3A | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3D | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA3D | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SEMG1 | c.291dup p.R98Tfs*12 | Frame Shift Ins (INS) | VAF 40/128 reads (31%) | called by mutect2, pindel, varscan2
- SETBP1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- SETBP1 | c.1772A>T p.K591M | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SGK1 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SI | c.5078G>T p.C1693F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SIPA1L2 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SIPA1L3 | c.2792G>T p.G931V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SLC12A1 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A6 | c.1998A>T p.L666F (on ENST00000354181 / NM_001365088.1; = p.L615F on NM_005135.2) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC25A32 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A5 | c.599-1G>T p.X200_splice | Splice Site (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- SLC26A5 | c.1725G>T p.M575I | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC41A2 | c.967G>T p.G323C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- SLC45A3 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | called by muse, varscan2
- SLC8A1 | c.795G>T p.R265S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- SLC9C1 | c.2075T>G p.L692R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SMCO1 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SMIM7 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SPATA31A1 | c.2036C>A p.P679Q | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- SPZ1 | c.443C>A p.T148N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- SULT2A1 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL4 | c.1677G>T p.R559S | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SYTL4 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TARS3 | c.1221+1G>T p.X407_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- TARS3 | c.697T>C p.W233R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- TAS1R2 | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- TBC1D7 | c.660A>T p.L220F | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TBC1D8B | c.1996G>T p.V666L | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D8B | c.2529C>G p.F843L | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2
- TBX21 | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- TCEAL5 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 105/377 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); called by muse, varscan2
- TENM2 | c.2981T>A p.V994E (on ENST00000518659 / NM_001122679.2; = p.V762E on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENT5D | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2
- TEX14 | c.4361C>A p.P1454Q (on ENST00000240361 / NM_001201457.2; = p.P1408Q on NM_031272.5) | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TGM5 | c.2133C>A p.Y711* (on ENST00000220420 / NM_201631.4; = p.Y629* on NM_004245.4) | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- TIAM2 | c.532C>G p.H178D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- TLR7 | c.1562G>T p.C521F | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132B | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TMEM252 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM39A | c.1273A>T p.I425F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- TMEM41B | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMPRSS7 | c.1915G>C p.E639Q (on ENST00000452346; = p.E513Q on NM_001042575.2) | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TNIK | c.2009del p.P670Qfs*14 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- TNRC6C | c.3176G>T p.G1059V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- TNXB | c.4837del p.A1613Pfs*13 (on ENST00000647633; = p.A1366Pfs*13 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- TOPORS | c.2143G>T p.G715W | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRAT1 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1486-2A>T p.X496_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- TRPV5 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TSHZ1 | c.2080G>T p.G694C (on ENST00000580243 / NM_001308210.2; = p.G649C on NM_005786.6) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- TSPAN6 | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TTN | c.42058G>T p.V14020L (on ENST00000591111; = p.V6596L on NM_003319.4) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TTN | c.30859C>A p.P10287T (on ENST00000591111; = p.P9360T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/199 reads (25%) | PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TTN | c.24127C>A p.P8043T (on ENST00000591111; = p.P7116T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.22565G>T p.S7522I (on ENST00000591111; = p.S6595I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TWSG1 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- UBE2NL | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- UBE3B | c.1382G>T p.C461F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- UNC5D | c.1524G>T p.R508S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP26 | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- USP4 | c.2176G>C p.D726H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- VASP | c.1091A>G p.E364G | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VCAN | c.8359C>T p.L2787F | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- VNN2 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- WDFY3 | c.9652T>G p.C3218G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- WDR59 | c.1950G>T p.Q650H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WIPF1 | c.1129+1G>T p.X377_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- ZCCHC13 | c.379_380delinsT p.Q127Wfs*45 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by pindel, varscan2*
- ZCCHC8 | c.1651G>T p.G551C | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- ZEB1 | c.3283G>C p.D1095H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ZFYVE9 | c.1358G>A p.C453Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZGRF1 | c.2842A>T p.T948S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF236 | c.2314C>T p.Q772* | Nonsense Mutation (SNP) | VAF 43/149 reads (29%) | called by muse, mutect2, varscan2
- ZNF398 | c.367A>T p.R123W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF521 | c.1908T>G p.C636W | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF521 | c.1727A>C p.K576T | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.1616C>G p.S539C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, varscan2
- ZNF536 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, varscan2
- ZNF547 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ZNF571 | c.1523A>T p.D508V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF572 | c.1404C>A p.Y468* | Nonsense Mutation (SNP) | VAF 15/345 reads (4%) | called by muse, mutect2
- ZNF582 | c.779G>C p.C260S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF597 | c.486C>A p.D162E | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ZP4 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZP4 | c.187dup p.L63Pfs*8 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- ZRANB1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ABCA13 | c.4329T>C p.N1443= | Silent (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2
- AC245033.1 | c.1737G>A p.T579= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as rs1008996512; called by muse, mutect2
- ADAMTS5 | c.2478G>T p.T826= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs373445194; called by muse, mutect2, varscan2
- ADCY8 | c.3201A>T p.S1067= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs1185797677; called by muse, mutect2, varscan2
- ADCY8 | c.2517G>T p.T839= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs755447347, COSV53903927; called by muse, mutect2, varscan2
- ADGRG4 | c.2148C>T p.A716= | Silent (SNP) | VAF 179/482 reads (37%) | called by muse, mutect2, varscan2
- ADGRG4 | c.6081T>A p.P2027= | Silent (SNP) | VAF 88/222 reads (40%) | called by muse, varscan2
- AHSG | c.192T>C p.D64= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs777775803; called by muse, mutect2, varscan2
- AK1 | c.357C>T p.D119= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1225543302, COSV56344730; called by muse, mutect2, varscan2
- AL035460.1 | c.45G>T p.P15= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs748066707; called by muse, mutect2, varscan2
- ANKZF1 | c.1707G>T p.R569= | Silent (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.1728G>C p.L576= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1480565380; called by muse, mutect2, varscan2
- ARHGEF37 | c.453G>T p.A151= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100382011; called by muse, mutect2, varscan2
- ARMC3 | c.2292A>T p.L764= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- ATP11C | c.2445G>T p.L815= | Silent (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- BRPF1 | c.1095G>T p.T365= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs1159225087, COSV57404935; called by muse, mutect2, varscan2
- C6orf118 | c.1167T>A p.T389= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- CACNA1E | c.2784A>T p.T928= | Silent (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.387C>T p.D129= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- CADM2 | c.984C>A p.S328= (on ENST00000407528 / NM_001167674.2; = p.S330= on NM_153184.4) | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV67403591; called by muse, mutect2, varscan2
- CCDC33 | c.1035G>C p.L345= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- CD163L1 | c.2331T>A p.T777= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- CD86 | c.823C>A p.R275= (on ENST00000330540 / NM_175862.5; = p.R269= on NM_006889.4) | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as rs566906411; called by muse, mutect2, varscan2
- CDH2 | c.1608A>G p.K536= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV52277304; called by mutect2, varscan2
- CDH8 | c.2367C>G p.L789= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1263717105, COSV100183961, COSV54868623; called by muse, mutect2, varscan2
- CFAP65 | c.5172C>T p.S1724= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1225124086; called by muse, mutect2, varscan2
- CHRFAM7A | c.606G>A p.L202= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs1286616120; called by muse, mutect2, varscan2
- CHRM3 | c.180G>A p.L60= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- CLK2 | c.1401G>T p.R467= (on ENST00000368361 / NM_001294339.2; = p.R466= on NM_003993.4) | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV56943603; called by muse, mutect2, varscan2
- CNTN5 | c.2067G>C p.L689= | Silent (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- COL6A3 | c.8709A>G p.P2903= | Silent (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- COL9A3 | c.1633A>C p.R545= | Silent (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- CPO | c.639A>G p.P213= | Silent (SNP) | VAF 61/203 reads (30%) | called by muse, mutect2, varscan2
- CRB1 | c.3279G>T p.L1093= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- CRYBG1 | c.4461A>G p.L1487= | Silent (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- CSMD2 | c.3336C>A p.P1112= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- CTAGE6 | c.699A>G p.V233= | Silent (SNP) | VAF 24/196 reads (12%) | called by muse, mutect2, varscan2
- CUX1 | c.3810A>T p.S1270= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- DAAM2 | c.1152G>C p.L384= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1359482727; called by mutect2, varscan2
- DCAF8L1 | c.1419C>A p.I473= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV71595483; called by muse, mutect2, varscan2
- DDX60 | c.1647C>G p.V549= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV67095081; called by muse, mutect2, varscan2
- DIP2C | c.1524G>T p.L508= | Silent (SNP) | VAF 118/183 reads (64%) | called by muse, mutect2, varscan2
- EDC4 | c.2295G>A p.E765= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV59301660; called by muse, mutect2, varscan2
- EGR1 | c.918C>G p.A306= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- ENGASE | c.804G>A p.V268= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs527984991; called by muse, mutect2, varscan2
- ENPP1 | c.417G>T p.T139= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs749954752, COSV62933658; called by muse, mutect2, varscan2
- EPB41L3 | c.1494G>C p.R498= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- EYA1 | c.540C>T p.Y180= | Silent (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- FANCL | c.63G>T p.S21= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV52078115, COSV99287650; called by muse, mutect2, varscan2
- FCAMR | c.579C>A p.I193= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100249486; called by muse, mutect2, varscan2
- FCRL5 | c.2178C>G p.S726= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- FGF1 | c.159C>T p.S53= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs759484659; called by muse, mutect2
- FGFR4 | c.36G>T p.L12= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- FHOD3 | c.387C>T p.S129= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs774533065, COSV57186785; called by muse, mutect2, varscan2
- FREM2 | c.4758C>A p.T1586= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV54853857; called by muse, mutect2, varscan2
- FUT9 | c.759C>A p.I253= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- FYB1 | c.1047C>A p.P349= | Silent (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- GAREM1 | c.1512G>A p.V504= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- GPR78 | c.831C>A p.I277= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- GRID2 | c.2559G>C p.T853= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99938441; called by muse, mutect2, varscan2
- GRIK2 | c.351A>T p.A117= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as rs1414945767; called by muse, mutect2, varscan2
- GZF1 | c.87C>T p.H29= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- H3C6 | c.270G>A p.V90= | Silent (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- HDAC9 | c.1233T>A p.L411= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- HDAC9 | c.3108C>A p.T1036= (on ENST00000441542 / NM_178425.3; = p.T1033= on NM_178423.3) | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV101286418, COSV101286738; called by muse, mutect2, varscan2
- HIVEP2 | c.6201A>G p.K2067= | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- HOXC4 | c.570C>A p.A190= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs1436426514; called by muse, mutect2, varscan2
- HTATSF1 | c.2220T>C p.T740= | Silent (SNP) | VAF 51/419 reads (12%) | called by muse, mutect2, varscan2
- HTR1A | c.924C>A p.P308= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- HTR5A | c.90C>A p.R30= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- IGLV2-8 | c.24C>T p.L8= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- IGSF9B | c.3465G>T p.P1155= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1017951332, COSV58064335, COSV58067175; called by muse, mutect2, varscan2
- IKBKB | c.2127G>T p.V709= | Silent (SNP) | VAF 65/153 reads (42%) | called by muse, mutect2, varscan2
- IL2RG | c.814T>C p.L272= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV99340460; called by muse, mutect2, varscan2
- KCTD16 | c.183G>T p.T61= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs766844514; called by muse, mutect2, varscan2
- KHDRBS2 | c.231G>T p.V77= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs767164811, COSV99830945; called by muse, mutect2, varscan2
- KLHL41 | c.363C>A p.V121= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- KRTAP10-4 | c.1113C>A p.P371= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs370710609; called by muse, mutect2, varscan2
- LAMB4 | c.4248G>T p.T1416= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- LRRC52 | c.750C>A p.L250= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- MAGEB1 | c.738C>A p.T246= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100974814; called by muse, mutect2, varscan2
- MAGEC2 | c.582C>A p.G194= | Silent (SNP) | VAF 230/611 reads (38%) | catalogued as COSV55998146, COSV99909548; called by muse, mutect2, varscan2
- MARCHF11 | c.1176G>T p.S392= | Silent (SNP) | VAF 62/274 reads (23%) | called by muse, mutect2, varscan2
- MC4R | c.12C>T p.S4= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs757561015; called by muse, mutect2, varscan2
- MFSD6L | c.1125T>C p.T375= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2
- MYBPC2 | c.1947G>T p.S649= | Silent (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- NACA2 | c.141C>A p.T47= | Silent (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- NDST4 | c.570A>G p.L190= | Silent (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- NWD1 | c.2181G>T p.R727= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- NXF3 | c.723G>T p.S241= | Silent (SNP) | VAF 68/287 reads (24%) | called by muse, mutect2, varscan2
- OR2A12 | c.534T>C p.C178= | Silent (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- OR2T3 | c.819T>A p.A273= | Silent (SNP) | VAF 82/630 reads (13%) | called by muse, mutect2
- OR2T34 | c.819T>A p.A273= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2
- OR4D2 | c.570T>A p.T190= | Silent (SNP) | VAF 39/199 reads (20%) | called by muse, mutect2, varscan2
- OR51I1 | c.687C>A p.V229= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- OR6C65 | c.468C>A p.P156= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV65569774; called by muse, mutect2, varscan2
- PAPPA | c.1785G>A p.E595= | Silent (SNP) | VAF 76/285 reads (27%) | catalogued as COSV60283032; called by muse, mutect2, varscan2
- PCDH9 | c.1788G>T p.V596= | Silent (SNP) | VAF 60/103 reads (58%) | catalogued as COSV60537622; called by muse, mutect2, varscan2
- PCDHAC1 | c.369C>T p.L123= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- PCDHB16 | c.1227C>A p.L409= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.2274T>A p.A758= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.465A>G p.P155= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- PCLO | c.3639A>C p.P1213= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- PEX1 | c.1683C>T p.S561= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- PHOX2B | c.102T>C p.S34= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- PKHD1 | c.11361A>T p.S3787= | Silent (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- PLB1 | c.102G>A p.G34= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.429G>T p.V143= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- PNPLA4 | c.156G>T p.L52= | Silent (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- POTEF | c.2520G>A p.L840= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs879223087; called by muse, mutect2, varscan2
- PRDM15 | c.1005G>T p.G335= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1490384250; called by muse, mutect2, varscan2
- PROKR1 | c.591C>T p.S197= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs1181649281; called by muse, mutect2, varscan2
- PRR16 | c.765C>A p.P255= (on ENST00000407149 / NM_001300783.2; = p.P232= on NM_016644.2) | Silent (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- PTCH1 | c.765G>T p.R255= | Silent (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1530G>C p.A510= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.4308G>T p.R1436= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- REC8 | c.180G>T p.L60= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs771866577; called by muse, mutect2, varscan2
- RESF1 | c.270A>G p.V90= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- RLBP1 | c.198G>T p.L66= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99175375; called by muse, mutect2, varscan2
- RPE65 | c.1461G>A p.L487= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99254397; called by muse, mutect2
- RUVBL2 | c.78C>G p.S26= | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- RYR2 | c.1453C>A p.R485= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as rs766420655, COSV63718535; called by muse, mutect2, varscan2
- RYR2 | c.1590G>T p.L530= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as rs765883801; called by muse, mutect2, varscan2
- RYR2 | c.14877G>T p.R4959= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- RYR3 | c.1119T>G p.T373= | Silent (SNP) | VAF 40/235 reads (17%) | catalogued as COSV101212027, COSV101215037, COSV66780594; called by muse, mutect2, varscan2
- SARM1 | c.1215C>A p.I405= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- SETD6 | c.1362C>A p.A454= (on ENST00000219315 / NM_001160305.4; = p.A430= on NM_024860.3) | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- SH2D1A | c.234G>A p.R78= | Silent (SNP) | VAF 83/307 reads (27%) | called by muse, mutect2, varscan2
- SLC15A1 | c.819C>A p.L273= | Silent (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- SLC20A2 | c.675G>C p.L225= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs1183598680; called by muse, mutect2, varscan2
- SLC24A3 | c.153C>A p.L51= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- SLC28A1 | c.1785G>T p.G595= | Silent (SNP) | VAF 38/193 reads (20%) | catalogued as rs750902935; called by muse, mutect2, varscan2
- SLC41A1 | c.1350G>A p.L450= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- SLC44A3 | c.1056G>T p.L352= (on ENST00000271227 / NM_001114106.3; = p.L304= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs765630358; called by muse, mutect2, varscan2
- SLC45A1 | c.1752C>T p.A584= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- SNX27 | c.945G>C p.V315= | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- SPAG17 | c.4479A>G p.V1493= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- SPATS1 | c.291C>A p.T97= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs775737609; called by muse, mutect2, varscan2
- SPTBN5 | c.3651G>T p.V1217= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- STAMBPL1 | c.1383C>A p.L461= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100905306; called by muse, mutect2, varscan2
- STK17B | c.696A>G p.T232= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs567859155, COSV55827549; called by muse, mutect2, varscan2
- STON1 | c.138C>A p.G46= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1368797481; called by muse, mutect2, varscan2
- SYNDIG1 | c.612C>A p.S204= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- TACR3 | c.762G>T p.L254= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- TECTA | c.2310G>T p.R770= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1408426770; called by muse, mutect2, varscan2
- TENT5C | c.774A>T p.T258= | Silent (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- TENT5D | c.51G>A p.L17= | Silent (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2
- TEP1 | c.7494A>G p.E2498= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs952500501; called by muse, mutect2, varscan2
- TMEM117 | c.1248A>G p.R416= | Silent (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- TMEM119 | c.540C>T p.T180= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- TMEM132A | c.333C>T p.V111= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- TMEM67 | c.1146C>T p.I382= | Silent (SNP) | VAF 48/196 reads (24%) | called by muse, mutect2, varscan2
- TOMM20 | c.270A>G p.V90= | Silent (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- TRPC7 | c.1422A>G p.L474= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- TRPM2 | c.1488G>A p.K496= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- TSEN2 | c.969A>G p.L323= | Silent (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.71559C>T p.D23853= (on ENST00000591111; = p.D16429= on NM_003319.4) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs370908118; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- USH2A | c.11973C>A p.P3991= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs760693392; called by muse, mutect2, varscan2
- USP16 | c.15G>A p.R5= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1271106790; called by mutect2, varscan2
- ZBTB38 | c.1824A>T p.P608= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- ZIC4 | c.330C>G p.P110= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV101267765; called by muse, mutect2, varscan2
- ZNF536 | c.417C>T p.F139= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV62818509, COSV62823576; called by muse, mutect2, varscan2
- ZNF536 | c.2082C>G p.V694= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, varscan2
- ADARB2 | c.101-147687C>A | Intron (SNP) | VAF 30/123 reads (24%) | catalogued as rs1233022510; called by muse, mutect2
- ADGRL3 | c.3944-1930G>T | Intron (SNP) | VAF 17/73 reads (23%) | catalogued as rs1221860656, COSV72232053; called by muse, mutect2, varscan2
- AFDN | c.4812+13G>T | Intron (SNP) | VAF 132/364 reads (36%) | called by muse, mutect2, varscan2
- AKR1D1 | c.690-176C>A | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as rs1451463096; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849006 C>T | 5'Flank (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- BTN2A3P | n.343G>T | RNA (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- FYN | c.862+589G>T | Intron (SNP) | VAF 29/102 reads (28%) | catalogued as rs1488200068; called by muse, varscan2
- KCNAB1 | c.276-129640C>A | Intron (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- L1CAM | chrX:153886969 A>G | 5'Flank (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10555A>T | Intron (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- NT5E | c.*2C>A | 3'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- OR2W5 | n.663G>T | RNA (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- OR52A4P | n.599G>T | RNA (SNP) | VAF 60/221 reads (27%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.930-6252A>G | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as rs768880228; called by muse, mutect2, varscan2
- RBFOX1 | c.*1A>T | 3'UTR (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- RN7SL484P | chr15:99792122 G>T | 3'Flank (SNP) | VAF 16/46 reads (35%) | catalogued as rs1397719690; called by muse, mutect2, varscan2
- SETX | c.7287+183G>T | Intron (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99810714; called by muse, mutect2, varscan2
- VWC2 | c.*2C>T | 3'UTR (SNP) | VAF 23/95 reads (24%) | catalogued as rs766742451, COSV61485092; called by muse, mutect2, varscan2
- WASF4P | n.563G>T | RNA (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- XKRX | c.-7C>A | 5'UTR (SNP) | VAF 122/524 reads (23%) | called by muse, mutect2, varscan2
